Somatic mutation profile of tumor specimen 0DSBYG from CCDI case PBCHUB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 20.7 years (7,552 days).
Specimen 0DSBYG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0468201b-c5d4-4efa-8db1-c5e254f34d90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSBY7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/832d6ec8-a478-48c7-bb91-8753075c04b0

The open-access MAF lists 10,413 somatic variants for this specimen: 6,541 protein-altering or splice-affecting, 1,776 silent, 2,096 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,298, Silent 1,776, Intron 1,250, Frame Shift Ins 492, 3'UTR 472, Nonsense Mutation 342, 5'UTR 254, Splice Site 246, Splice Region 127, 5'Flank 47, RNA 42, 3'Flank 31.

Variants (750 of 10,413; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 35/149 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASPA | c.244dup p.M82Nfs*8 | Frame Shift Ins (INS) | VAF 244/883 reads (28%) | catalogued as rs756198538; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDKL5 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 246/1125 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267608435, CM0910470; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 240/825 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057521930, CD143085, CM1512397, COSV58581693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A1 | c.4697dup p.E1571Rfs*53 | Frame Shift Ins (INS) | VAF 62/292 reads (21%) | catalogued as rs1131691996; ClinVar: pathogenic; called by mutect2, varscan2
- DYNC2H1 | c.8512C>T p.R2838* | Nonsense Mutation (SNP) | VAF 138/631 reads (22%) | catalogued as rs137853032, CM091951, COSV62103744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.4825dup p.T1609Nfs*4 | Frame Shift Ins (INS) | VAF 238/728 reads (33%) | catalogued as rs397514036; ClinVar: pathogenic; called by mutect2, varscan2
- IL7R | c.361dup p.I121Nfs*8 | Frame Shift Ins (INS) | VAF 84/520 reads (16%) | catalogued as rs869312857; ClinVar: pathogenic; called by mutect2, varscan2
- KCNH2 | c.2775dup p.P926Afs*14 | Frame Shift Ins (INS) | VAF 57/193 reads (30%) | catalogued as rs794728455; ClinVar: pathogenic; called by mutect2, varscan2
- KCNH2 | c.453dup p.T152Hfs*180 | Frame Shift Ins (INS) | VAF 108/460 reads (23%) | catalogued as rs761863251; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KCNQ1 | c.1265dup p.F423Vfs*40 | Frame Shift Ins (INS) | VAF 122/284 reads (43%) | catalogued as rs397508083; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 206/738 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.710dup p.Y238Vfs*2 | Frame Shift Ins (INS) | VAF 197/804 reads (25%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 45/164 reads (27%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- P3H2 | c.297dup p.G100Rfs*7 | Frame Shift Ins (INS) | VAF 36/144 reads (25%) | catalogued as rs875989838; ClinVar: pathogenic; called by mutect2, varscan2
- PEX10 | c.26dup p.E10Gfs*41 | Frame Shift Ins (INS) | VAF 20/106 reads (19%) | catalogued as rs1553232917; ClinVar: likely pathogenic; called by mutect2, varscan2
- PEX12 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 99/713 reads (14%) | catalogued as rs61752103, CM981517, COSV56777816; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.8311G>A p.E2771K | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518897, CM010386, CX1210805; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD51 | c.855dup p.P286Tfs*37 | Frame Shift Ins (INS) | VAF 133/818 reads (16%) | catalogued as rs34091239; ClinVar: pathogenic; called by mutect2, varscan2
- RPS10-NUDT3 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 81/320 reads (25%) | catalogued as rs267607022, CM101046, COSV58243116; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.1441dup p.S481Kfs*17 | Frame Shift Ins (INS) | VAF 258/896 reads (29%) | catalogued as rs745774620; ClinVar: likely pathogenic; called by mutect2, varscan2
- TCOF1 | c.4365dup p.E1456Rfs*15 (on ENST00000377797 / NM_001135243.1; = p.E1379Rfs*15 on NM_000356.4) | Frame Shift Ins (INS) | VAF 76/432 reads (18%) | catalogued as rs587776585; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 157/515 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52676197, COSV52682212, COSV52698349, COSV52762255; called by muse, mutect2, varscan2
- TPO | c.2421del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 140/468 reads (30%) | catalogued as rs760307139, COSV100220194; ClinVar: pathogenic; called by mutect2, varscan2
- TUBB4A | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 55/344 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as rs886041010, CM146501, CM1513912; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP53 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 145/1073 reads (14%) | catalogued as rs376368459; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AANAT | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551960202; called by muse, mutect2, varscan2
- AARS1 | c.334-2A>G p.X112_splice | Splice Site (SNP) | VAF 67/513 reads (13%) | catalogued as rs752432782; called by muse, mutect2, varscan2
- ABCA1 | c.5013C>A p.S1671R | Missense Mutation (SNP) | VAF 126/869 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1382766437; called by muse, mutect2, varscan2
- ABCA12 | c.4949A>G p.Y1650C (on ENST00000272895 / NM_173076.3; = p.Y1332C on NM_015657.3) | Missense Mutation (SNP) | VAF 71/626 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199856299; called by muse, mutect2, varscan2
- ABCA3 | c.73A>C p.T25P | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV57058790; called by muse, mutect2, varscan2
- ABCB10 | c.973G>T p.V325L | Missense Mutation (SNP) | VAF 121/909 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs1321660648; called by muse, mutect2, varscan2
- ABCC1 | c.1095C>A p.F365L | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs776470140, COSV60684942; called by muse, varscan2
- ABCC1 | c.3332C>A p.A1111D | Missense Mutation (SNP) | VAF 165/602 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100579451; called by muse, mutect2, varscan2
- ABCD2 | c.1429G>A p.G477R | Missense Mutation (SNP) | VAF 110/781 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as rs192072180; called by muse, mutect2, varscan2
- ABCF2 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 38/1185 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs1315137844; called by muse, mutect2
- ABCF3 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs371929198, COSV53049971; called by muse, mutect2, varscan2
- ABCF3 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767510133; called by muse, mutect2, varscan2
- ABCG2 | c.427T>C p.S143P | Missense Mutation (SNP) | VAF 270/870 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346765745; called by muse, mutect2, varscan2
- ABI1 | c.118-1G>T p.X40_splice | Splice Site (SNP) | VAF 24/512 reads (5%) | catalogued as COSV100697948, COSV61016340; called by muse, mutect2
- ABL1 | c.208T>A p.Y70N | Missense Mutation (SNP) | VAF 166/956 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583579; called by muse, mutect2, varscan2
- ABL2 | c.2264G>A p.R755H (on ENST00000502732 / NM_007314.4; = p.R740H on NM_005158.5) | Missense Mutation (SNP) | VAF 156/576 reads (27%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.034); catalogued as rs147435995; called by muse, mutect2, varscan2
- ABLIM2 | c.1490G>A p.R497K (on ENST00000341937 / NM_001130084.2; = p.R446K on NM_032432.5) | Missense Mutation (SNP) | VAF 93/619 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV99590314; called by muse, mutect2, varscan2
- ABLIM3 | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58644527; called by muse, mutect2, varscan2
- AC100868.1 | c.1999C>A p.L667I | Missense Mutation (SNP) | VAF 70/375 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV99225982; called by muse, mutect2, varscan2
- ACAD10 | c.1911C>A p.S637R | Missense Mutation (SNP) | VAF 59/600 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.216); catalogued as COSV58156947; called by muse, mutect2
- ACAP2 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 146/1028 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV58755497; called by mutect2, varscan2
- ACKR4 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 190/749 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV51442190; called by mutect2, varscan2
- ACO1 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 200/655 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59376248; called by muse, varscan2
- ACSM2A | c.1212dup p.G405Rfs*48 (on ENST00000219054; = p.G326Rfs*48 on NM_001308169.2) | Frame Shift Ins (INS) | VAF 152/502 reads (30%) | catalogued as rs755296455; called by mutect2, varscan2
- ACSM4 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 184/644 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV68068045; called by muse, mutect2, varscan2
- ACTA2 | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 118/947 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.831); catalogued as CM149850; called by mutect2, varscan2
- ACTN3 | c.458T>A p.I153N | Missense Mutation (SNP) | VAF 30/375 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs988327948; called by muse, mutect2
- ACVR1B | c.1059C>A p.D353E | Missense Mutation (SNP) | VAF 215/691 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57776121; called by muse, mutect2, varscan2
- ADAM15 | c.2481G>T p.Q827H (on ENST00000356955 / NM_207197.3; = p.Q778H on NM_003815.5) | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV55128775; called by muse, mutect2, varscan2
- ADAM30 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 138/530 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs984058539; called by muse, mutect2, varscan2
- ADAMTS1 | c.1271A>G p.N424S | Missense Mutation (SNP) | VAF 200/778 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53170291; called by muse, mutect2, varscan2
- ADAMTS10 | c.1733G>T p.R578M | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV99547318; called by muse, mutect2, varscan2
- ADAMTS13 | c.3578G>A p.G1193D | Missense Mutation (SNP) | VAF 131/443 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479241110; called by muse, mutect2, varscan2
- ADAMTS3 | c.228C>A p.N76K | Missense Mutation (SNP) | VAF 233/743 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.08); catalogued as rs1344539242; called by muse, mutect2, varscan2
- ADAMTS5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 156/563 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286298815, COSV53175922; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185377791; called by muse, mutect2, varscan2
- ADARB2 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs749880767; called by muse, mutect2, varscan2
- ADCY4 | c.2593T>C p.Y865H | Missense Mutation (SNP) | VAF 134/552 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1052181602; called by muse, mutect2, varscan2
- ADCY6 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359336446, COSV100326566; called by mutect2, varscan2
- ADGRG4 | c.5348dup p.N1783Kfs*3 | Frame Shift Ins (INS) | VAF 261/903 reads (29%) | catalogued as rs760259488; called by mutect2, varscan2
- ADGRG6 | c.3499G>T p.G1167C | Missense Mutation (SNP) | VAF 120/865 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368848974; called by muse, mutect2, varscan2
- ADGRL2 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 137/916 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs370124207; called by muse, mutect2, varscan2
- ADGRV1 | c.16455G>T p.Q5485H | Missense Mutation (SNP) | VAF 46/1138 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV67984115, COSV67994367; called by muse, mutect2
- ADI1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 110/399 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as rs983624043; called by muse, mutect2, varscan2
- ADIPOR2 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 276/1060 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1226420097; called by muse, mutect2, varscan2
- ADNP | c.3065A>T p.D1022V | Missense Mutation (SNP) | VAF 197/743 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.326); catalogued as COSV100823661; called by muse, mutect2, varscan2
- ADRA1D | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as rs1474556755; called by muse, mutect2, varscan2
- ADRB3 | c.874T>C p.C292R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1040324670; called by muse, mutect2, varscan2
- AFM | c.1627C>A p.L543I | Missense Mutation (SNP) | VAF 143/625 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV56920934; called by muse, mutect2, varscan2
- AFTPH | c.2608A>G p.T870A (on ENST00000238855 / NM_203437.3; = p.T842A on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 301/1007 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.954); catalogued as rs751465275; called by muse, mutect2, varscan2
- AGAP1 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 244/766 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs755702930; called by muse, mutect2, varscan2
- AGAP3 | c.1463G>A p.R488H (on ENST00000622464; = p.R524H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs925378481, COSV68242968; called by muse, varscan2
- AGBL2 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 81/694 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.034); catalogued as COSV54093593; called by muse, mutect2, varscan2
- AGBL5 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 122/429 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.329); catalogued as COSV59935463; called by muse, mutect2, varscan2
- AGBL5 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 80/640 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.57); catalogued as rs1468261345; called by muse, mutect2, varscan2
- AGGF1 | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 72/600 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs144241087; called by muse, mutect2, varscan2
- AGL | c.1936A>G p.I646V | Missense Mutation (SNP) | VAF 222/1361 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs376666809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGO2 | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 104/452 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV99596295; called by muse, mutect2
- AGO2 | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV99595654; called by muse, mutect2, varscan2
- AGXT | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100280040; called by muse, mutect2, varscan2
- AKAP8 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 72/435 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs764482753, COSV54102595; called by muse, mutect2, varscan2
- AKIP1 | c.303+1G>A p.X101_splice | Splice Site (SNP) | VAF 152/518 reads (29%) | catalogued as rs771775222; called by muse, mutect2, varscan2
- AKR1B15 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 222/841 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.228); catalogued as COSV71152967; called by muse, mutect2, varscan2
- AKR1B15 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 108/792 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV101423347; called by mutect2, varscan2
- AKR7L | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs755968121; called by muse, mutect2, varscan2
- AL121899.2 | c.157A>G p.R53G | Missense Mutation (SNP) | VAF 94/589 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198470; called by muse, mutect2, varscan2
- ALDH3B2 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 130/389 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV62427795; called by muse, mutect2, varscan2
- ALKBH4 | c.521G>T p.W174L | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363974238; called by muse, mutect2, varscan2
- ALPK3 | c.2240C>A p.P747H | Missense Mutation (SNP) | VAF 118/352 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51932335; called by muse, mutect2, varscan2
- ALS2 | c.3292G>T p.D1098Y | Missense Mutation (SNP) | VAF 268/1108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51891152; called by muse, mutect2, varscan2
- AMHR2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs868480524; called by muse, mutect2, varscan2
- AMPD2 | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 182/570 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV99857654; called by muse, mutect2, varscan2
- ANAPC5 | c.1076T>G p.V359G | Missense Mutation (SNP) | VAF 119/508 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV55844146; called by muse, mutect2, varscan2
- ANGPT1 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 146/689 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400681492; called by muse, mutect2, varscan2
- ANGPTL3 | c.1026A>C p.K342N | Missense Mutation (SNP) | VAF 40/1116 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV52023876; called by muse, mutect2
- ANK3 | c.11557A>C p.T3853P | Missense Mutation (SNP) | VAF 96/681 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs762042515; called by muse, varscan2
- ANKFY1 | c.2110G>A p.A704T (on ENST00000341657 / NM_001330063.2; = p.A705T on NM_016376.5) | Missense Mutation (SNP) | VAF 151/483 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1442615858, COSV58915465; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2375G>T p.R792I | Missense Mutation (SNP) | VAF 87/725 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51846427, COSV51853752; called by muse, mutect2, varscan2
- ANKIB1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 120/942 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs759267009; called by muse, mutect2, varscan2
- ANKRD18A | c.1126A>G p.N376D | Missense Mutation (SNP) | VAF 147/1186 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV101294909; called by muse, mutect2, varscan2
- ANKRD26 | c.3702dup p.Q1235Tfs*17 | Frame Shift Ins (INS) | VAF 259/875 reads (30%) | catalogued as rs777688871; called by mutect2, varscan2
- ANKRD26 | c.1157A>C p.N386T | Missense Mutation (SNP) | VAF 249/911 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1469948289; called by muse, mutect2, varscan2
- ANKRD30B | c.756-1G>T p.X252_splice | Splice Site (SNP) | VAF 41/521 reads (8%) | catalogued as rs1196592781, COSV62819573; called by muse, mutect2
- ANKRD36 | c.4575dup p.D1526Rfs*17 | Frame Shift Ins (INS) | VAF 50/224 reads (22%) | catalogued as rs1487992945; called by mutect2, varscan2
- ANKRD36C | c.4764dup p.Q1589Tfs*11 | Frame Shift Ins (INS) | VAF 178/1363 reads (13%) | catalogued as rs200875477; called by mutect2, varscan2
- ANKRD36C | c.2834dup p.H946Afs*6 | Frame Shift Ins (INS) | VAF 376/1358 reads (28%) | catalogued as rs1488887683; called by mutect2, varscan2
- ANKS1A | c.2023A>G p.M675V | Missense Mutation (SNP) | VAF 177/679 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1324965587; called by muse, mutect2, varscan2
- ANKS1B | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 205/765 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs759628814; called by muse, mutect2, varscan2
- ANKS4B | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 110/666 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61139798; called by mutect2, varscan2
- ANO2 | c.2908C>T p.R970* (on ENST00000356134 / NM_001278597.3; = p.R974* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 38/356 reads (11%) | catalogued as rs569322226, COSV104401616; called by muse, mutect2, varscan2
- ANO4 | c.1311G>A p.W437* (on ENST00000392977 / NM_001286615.2; = p.W402* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 128/456 reads (28%) | catalogued as COSV100153592, COSV54614380; called by muse, varscan2
- ANO7 | c.1142+1G>T p.X381_splice (on ENST00000274979; = p.X327_splice on NM_001370694.2) | Splice Site (SNP) | VAF 59/488 reads (12%) | catalogued as COSV51468114; called by muse, mutect2, varscan2
- AOC1 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 120/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752926390; called by muse, mutect2, varscan2
- AOC2 | c.1223A>G p.H408R | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs758333385; called by muse, mutect2, varscan2
- AP002512.3 | c.393dup p.V132Cfs*22 | Frame Shift Ins (INS) | VAF 282/920 reads (31%) | catalogued as rs775245123; called by mutect2, varscan2
- APAF1 | c.2006A>T p.D669V (on ENST00000551964 / NM_181861.2; = p.D658V on NM_001160.3) | Missense Mutation (SNP) | VAF 90/750 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs756655231; called by muse, varscan2
- APBB1 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1242387872; called by muse, mutect2, varscan2
- APC | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 145/987 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57344895; called by muse, mutect2, varscan2
- APC | c.2268dup p.Q757Tfs*18 | Frame Shift Ins (INS) | VAF 366/1051 reads (35%) | catalogued as COSV57336078, COSV57383527; called by mutect2, varscan2
- APC | c.4625C>A p.P1542H | Missense Mutation (SNP) | VAF 171/1117 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57367875; called by muse, mutect2, varscan2
- API5 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 38/896 reads (4%) | catalogued as COSV101124503; called by muse, mutect2
- APLNR | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 145/509 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208391519; called by muse, mutect2, varscan2
- APOB | c.4928C>T p.A1643V | Missense Mutation (SNP) | VAF 161/501 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1008238083, COSV51931582; called by muse, mutect2, varscan2
- APOBEC3F | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 108/404 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV100415140; called by muse, mutect2, varscan2
- APOOL | c.151T>C p.S51P | Missense Mutation (SNP) | VAF 58/1371 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1241736002; called by muse, mutect2
- APPL2 | c.864-1G>A p.X288_splice | Splice Site (SNP) | VAF 96/362 reads (27%) | catalogued as rs750311966; called by muse, mutect2, varscan2
- AQR | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 41/197 reads (21%) | catalogued as COSV50029529, COSV50043410; called by muse, varscan2
- AREL1 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 104/710 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs780978467, COSV62666066; called by muse, mutect2, varscan2
- ARFGAP3 | c.687dup p.G230Rfs*14 | Frame Shift Ins (INS) | VAF 188/618 reads (30%) | catalogued as rs754931118; called by mutect2, varscan2
- ARFGEF1 | c.2491A>G p.I831V | Missense Mutation (SNP) | VAF 160/758 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1241949806; called by muse, mutect2, varscan2
- ARFGEF3 | c.3211C>T p.R1071C | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as rs764225934; called by muse, mutect2, varscan2
- ARHGAP18 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 282/950 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100936172; called by muse, mutect2, varscan2
- ARHGAP35 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as rs1472856587; called by muse, mutect2, varscan2
- ARHGEF4 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 108/748 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as rs762720636; called by muse, mutect2, varscan2
- ARID1B | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 114/442 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs780970034, COSV51660202; called by muse, mutect2, varscan2
- ARID2 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 282/927 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1320496837; called by muse, mutect2, varscan2
- ARL11 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 63/301 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs769707452, COSV56291336; called by muse, mutect2, varscan2
- ARL4A | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 120/913 reads (13%) | catalogued as COSV100775897; called by muse, mutect2, varscan2
- ARNTL2 | c.1870G>T p.G624* | Nonsense Mutation (SNP) | VAF 266/891 reads (30%) | catalogued as COSV53828485; called by muse, mutect2, varscan2
- ARPP19 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 183/622 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs749070045; called by muse, mutect2, varscan2
- ARPP21 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 41/1192 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51795289; called by muse, mutect2
- ASB12 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 85/794 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs763691336; called by muse, mutect2, varscan2
- ASCC3 | c.4751A>G p.D1584G | Missense Mutation (SNP) | VAF 318/1178 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100976332; called by muse, mutect2, varscan2
- ASCC3 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 215/1396 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1562341005; called by mutect2, varscan2
- ASIC4 | c.1357C>T p.R453* (on ENST00000347842 / NM_182847.3; = p.R472* on NM_018674.6) | Nonsense Mutation (SNP) | VAF 45/422 reads (11%) | catalogued as rs771596337, COSV61731572; called by muse, mutect2, varscan2
- ASPG | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 138/469 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs936468653; called by mutect2, varscan2
- ATAD2B | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 142/631 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174698065, COSV99477191; called by muse, mutect2, varscan2
- ATCAY | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs537155754; ClinVar: uncertain significance; called by muse, varscan2
- ATF7IP | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 311/1087 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1409123142, COSV53778159; called by muse, mutect2, varscan2
- ATG7 | c.262T>G p.Y88D | Missense Mutation (SNP) | VAF 36/1144 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as COSV61612461; called by muse, mutect2
- ATP10A | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 34/318 reads (11%) | catalogued as rs267604144, COSV63512941; called by muse, varscan2
- ATP11B | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 137/925 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV60033240; called by muse, mutect2, varscan2
- ATP1A2 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 106/778 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV63402254; called by muse, mutect2, varscan2
- ATP1A3 | c.2581+2T>C p.X861_splice (on ENST00000545399 / NM_001256214.2; = p.X848_splice on NM_152296.5) | Splice Site (SNP) | VAF 36/190 reads (19%) | catalogued as CS134724; called by muse, mutect2, varscan2
- ATP1B4 | c.524G>T p.W175L (on ENST00000218008 / NM_001142447.3; = p.W171L on NM_012069.5) | Missense Mutation (SNP) | VAF 201/818 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54312918; called by muse, mutect2, varscan2
- ATP2A1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 22/497 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100837320; called by muse, mutect2
- ATP6V0D2 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 177/718 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.325); catalogued as COSV53415701; called by muse, mutect2, varscan2
- ATP7A | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 125/929 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as COSV100431651; called by muse, mutect2, varscan2
- ATPAF1 | c.630dup p.V211Cfs*8 (on ENST00000574428; = p.V234Cfs*8 on NM_022745.4) | Frame Shift Ins (INS) | VAF 208/768 reads (27%) | catalogued as rs1310890099; called by mutect2, varscan2
- ATR | c.3899G>A p.R1300H | Missense Mutation (SNP) | VAF 337/1193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757622477, COSV63393489; called by muse, mutect2, varscan2
- ATRX | c.5024A>T p.D1675V | Missense Mutation (SNP) | VAF 364/1172 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV64871222; called by muse, mutect2, varscan2
- ATXN1 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.749); catalogued as rs756566157, COSV55209511; called by muse, varscan2
- AUNIP | c.220+1G>A p.X74_splice | Splice Site (SNP) | VAF 166/606 reads (27%) | catalogued as rs758124885; called by muse, mutect2, varscan2
- B3GALNT1 | c.567T>A p.N189K | Missense Mutation (SNP) | VAF 263/907 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs911299477; called by muse, mutect2, varscan2
- B3GALNT2 | c.1374T>A p.S458R | Missense Mutation (SNP) | VAF 295/998 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.2); catalogued as rs947476664; called by muse, varscan2
- B3GALNT2 | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 38/1038 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV58356099; called by muse, mutect2
- B4GALNT3 | c.448-1G>A p.X150_splice | Splice Site (SNP) | VAF 42/325 reads (13%) | catalogued as COSV56751278; called by muse, mutect2, varscan2
- B4GALNT3 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 63/501 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs145057819; called by muse, mutect2, varscan2
- BAZ1B | c.621dup p.G208Rfs*16 | Frame Shift Ins (INS) | VAF 228/728 reads (31%) | catalogued as rs1554575750; called by mutect2, varscan2
- BAZ2A | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 95/722 reads (13%) | catalogued as COSV51639412, COSV99466857; called by muse, mutect2, varscan2
- BAZ2B | c.6479dup p.W2161Vfs*12 | Frame Shift Ins (INS) | VAF 102/678 reads (15%) | catalogued as rs1553468309; called by mutect2, varscan2
- BAZ2B | c.2372G>A p.S791N | Missense Mutation (SNP) | VAF 187/648 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); catalogued as rs373439599; called by muse, mutect2, varscan2
- BBS5 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 51/505 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs758174159; called by muse, mutect2, varscan2
- BBX | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 51/432 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57883324; called by muse, mutect2, varscan2
- BCL7C | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 79/310 reads (25%) | catalogued as rs1437818575, COSV66692275; called by muse, mutect2, varscan2
- BCL9 | c.2572C>A p.P858T | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99325706; called by muse, mutect2, varscan2
- BCLAF1 | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 176/703 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1417547401, COSV50356976; called by muse, mutect2, varscan2
- BCOR | c.4929G>T p.E1643D (on ENST00000378444 / NM_001123385.2; = p.E1609D on NM_017745.6) | Missense Mutation (SNP) | VAF 134/629 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60704155; called by muse, mutect2, varscan2
- BCORL1 | c.3136C>A p.L1046M | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54408444; called by muse, mutect2, varscan2
- BDP1 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 313/880 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs964624642; called by muse, mutect2, varscan2
- BEGAIN | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62070301; called by muse, mutect2, varscan2
- BHLHE22 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.637); catalogued as rs539265530; called by muse, mutect2, varscan2
- BICD1 | c.2743dup p.R915Kfs*35 | Frame Shift Ins (INS) | VAF 100/698 reads (14%) | catalogued as rs1490532706; called by mutect2, varscan2
- BIN2 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 204/595 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs1221141071, COSV57203394; called by muse, mutect2, varscan2
- BIN3 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV52383816; called by muse, mutect2, varscan2
- BLMH | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 236/934 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1382347908; called by muse, varscan2
- BMP2K | c.2308G>A p.G770R | Missense Mutation (SNP) | VAF 184/739 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs1250260171; called by muse, varscan2
- BMP6 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.225); catalogued as rs1163123409, COSV51661407; called by muse, mutect2, varscan2
- BMPR1B | c.1204A>C p.S402R | Missense Mutation (SNP) | VAF 42/1446 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52781732; called by muse, mutect2
- BMPR2 | c.1645T>C p.S549P | Missense Mutation (SNP) | VAF 266/846 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1178061846; called by muse, mutect2, varscan2
- BNIP1 | c.371G>T p.R124M | Missense Mutation (SNP) | VAF 50/442 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777949267, COSV99199422; called by muse, mutect2, varscan2
- BOD1L1 | c.4345G>T p.E1449* | Nonsense Mutation (SNP) | VAF 155/1144 reads (14%) | catalogued as rs779677747; called by muse, mutect2, varscan2
- BOD1L1 | c.3334A>T p.T1112S | Missense Mutation (SNP) | VAF 251/946 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV50011537; called by mutect2, varscan2
- BPIFA3 | c.765A>G p.*255Wext*14 | Nonstop Mutation (SNP) | VAF 48/524 reads (9%) | catalogued as rs368201209; called by muse, mutect2
- BRCA1 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 94/547 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.63); catalogued as CD984127; called by muse, mutect2, varscan2
- BRD4 | c.3695G>A p.R1232Q | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs1023216999, COSV54583371, COSV99650198; called by muse, mutect2, varscan2
- BRMS1 | c.694-1G>A p.X232_splice | Splice Site (SNP) | VAF 87/348 reads (25%) | catalogued as rs778296746; called by muse, mutect2, varscan2
- BSN | c.5557G>T p.A1853S | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs1406837440; called by muse, mutect2, varscan2
- BSN | c.9166T>G p.F3056V | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs774857387; called by muse, mutect2, varscan2
- BTBD16 | c.1158T>G p.F386L | Missense Mutation (SNP) | VAF 93/401 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV53263355; called by muse, mutect2, varscan2
- BTK | c.1632-6T>C | Splice Region (SNP) | VAF 152/671 reads (23%) | catalogued as rs1555977501; called by muse, mutect2, varscan2
- BTK | c.591C>A p.I197= | Splice Region (SNP) | VAF 67/448 reads (15%) | catalogued as COSV58120418; called by muse, mutect2, varscan2
- BTN3A1 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 71/422 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); catalogued as COSV50025257; called by muse, mutect2, varscan2
- BVES | c.1005A>G p.I335M | Missense Mutation (SNP) | VAF 125/930 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1349238582; called by muse, varscan2
- C16orf87 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 331/1119 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.266); catalogued as rs751824128; called by muse, mutect2, varscan2
- C17orf80 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 36/1049 reads (3%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.769); catalogued as COSV104371504; called by muse, mutect2
- C19orf12 | c.67C>A p.L23M (on ENST00000392278 / NM_001031726.3; = p.L12M on NM_031448.6) | Missense Mutation (SNP) | VAF 78/520 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60364208; called by muse, mutect2, varscan2
- C1QTNF4 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as COSV56784373; called by muse, mutect2, varscan2
- C1orf158 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 93/608 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs757604143, COSV55346313, COSV55347418; called by muse, mutect2, varscan2
- C20orf194 | c.1692C>A p.F564L | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV99330438, COSV99330875; called by muse, mutect2, varscan2
- C2orf49 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 308/1144 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as rs1332346721, COSV51527370, COSV51527386; called by muse, mutect2, varscan2
- C3AR1 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 67/569 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs868285987; called by muse, mutect2, varscan2
- C5 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 149/920 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746776517; called by muse, mutect2, varscan2
- C5AR1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 116/368 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201523765; called by muse, mutect2, varscan2
- C5orf58 | c.83A>C p.K28T | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368222957; called by muse, varscan2
- CAAP1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 94/308 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.038); catalogued as rs774905644; called by muse, mutect2, varscan2
- CABIN1 | c.5473G>A p.A1825T | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs766348932, COSV54085013; called by muse, mutect2, varscan2
- CACNA1A | c.4240A>G p.K1414E | Missense Mutation (SNP) | VAF 23/640 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs932772664; ClinVar: uncertain significance; called by muse, mutect2
- CADPS | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 79/695 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs151301388; called by muse, mutect2, varscan2
- CADPS2 | c.3008+1G>A p.X1003_splice | Splice Site (SNP) | VAF 264/1011 reads (26%) | catalogued as rs769109496, COSV100465515; called by muse, mutect2, varscan2
- CALCRL | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 194/756 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66475091; called by muse, varscan2
- CAND1 | c.1435G>T p.G479* | Nonsense Mutation (SNP) | VAF 31/854 reads (4%) | catalogued as COSV101607345; called by muse, mutect2
- CAND2 | c.2107G>A p.V703I (on ENST00000456430 / NM_001162499.2; = p.V610I on NM_012298.3) | Missense Mutation (SNP) | VAF 106/334 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1559553989; called by muse, mutect2, varscan2
- CANX | c.1728G>T p.E576D | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs1485217155; called by muse, mutect2, varscan2
- CAP2 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 74/744 reads (10%) | catalogued as COSV57732547; called by muse, mutect2
- CAPN10 | c.122T>C p.I41T | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV99550688; called by muse, mutect2, varscan2
- CAPN12 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 32/142 reads (23%) | catalogued as rs1218312055; called by muse, mutect2, varscan2
- CAPN3 | c.498+1G>T p.X166_splice | Splice Site (SNP) | VAF 21/387 reads (5%) | catalogued as CS053452; called by muse, mutect2
- CAPZA2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 307/1183 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs773372818, COSV63266953; called by muse, mutect2, varscan2
- CARD14 | c.2437C>A p.L813M | Missense Mutation (SNP) | VAF 124/484 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58339142; called by muse, mutect2
- CARD6 | c.1694G>T p.W565L | Missense Mutation (SNP) | VAF 122/838 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV99620989; called by mutect2, varscan2
- CARD6 | c.1750A>G p.S584G | Missense Mutation (SNP) | VAF 105/704 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs755239866, COSV54569471; called by muse, mutect2, varscan2
- CARMIL1 | c.1451T>C p.I484T | Missense Mutation (SNP) | VAF 127/976 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1446509115; called by muse, mutect2, varscan2
- CASD1 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 106/819 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208186280; called by muse, mutect2, varscan2
- CASP8AP2 | c.3800A>C p.N1267T | Missense Mutation (SNP) | VAF 122/997 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52747197; called by muse, mutect2, varscan2
- CATSPERE | c.1698T>A p.Y566* | Nonsense Mutation (SNP) | VAF 141/921 reads (15%) | catalogued as COSV63679446; called by muse, mutect2, varscan2
- CBLC | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 154/489 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557856786, COSV54322587, COSV54323208; called by muse, mutect2, varscan2
- CBY2 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs759482874, COSV60119002; called by muse, mutect2, varscan2
- CC2D1B | c.2117T>C p.V706A | Missense Mutation (SNP) | VAF 66/494 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs939636188; called by muse, mutect2, varscan2
- CCDC141 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 292/1086 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1207823811; called by muse, mutect2, varscan2
- CCDC144A | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 140/343 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as rs1312259870; called by muse, mutect2, varscan2
- CCDC144A | c.2956C>A p.L986I | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1268136106; called by mutect2, varscan2
- CCDC175 | c.1010dup p.N337Kfs*2 | Frame Shift Ins (INS) | VAF 105/422 reads (25%) | catalogued as rs1043200326; called by mutect2, varscan2
- CCDC180 | c.1753A>G p.S585G | Missense Mutation (SNP) | VAF 136/923 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63828756; called by muse, mutect2, varscan2
- CCDC186 | c.780A>T p.E260D | Missense Mutation (SNP) | VAF 146/573 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV100991100; called by muse, mutect2, varscan2
- CCDC191 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 138/549 reads (25%) | catalogued as COSV55674025; called by muse, mutect2, varscan2
- CCDC70 | c.151dup p.I51Nfs*72 | Frame Shift Ins (INS) | VAF 125/582 reads (21%) | catalogued as rs752919705; called by mutect2, varscan2
- CCDC88C | c.653A>T p.D218V | Missense Mutation (SNP) | VAF 147/496 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66239929; called by muse, mutect2, varscan2
- CCIN | c.985A>G p.I329V | Missense Mutation (SNP) | VAF 131/413 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.833); catalogued as rs1224921533; called by muse, mutect2, varscan2
- CCL21 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 105/432 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs142482921, COSV99425655; called by muse, mutect2, varscan2
- CCN1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 130/518 reads (25%) | catalogued as COSV101486141; called by muse, varscan2
- CCN6 | c.931A>G p.K311E | Missense Mutation (SNP) | VAF 332/1156 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs781783002; called by muse, mutect2, varscan2
- CCNB3 | c.3149T>C p.I1050T | Missense Mutation (SNP) | VAF 125/823 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs782417581; called by muse, mutect2, varscan2
- CCR3 | c.-11-8T>C | Splice Region (SNP) | VAF 162/544 reads (30%) | catalogued as rs750564895; called by muse, varscan2
- CCR7 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs756277812; called by muse, mutect2, varscan2
- CCRL2 | c.610A>G p.M204V | Missense Mutation (SNP) | VAF 224/722 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs1447255747; called by muse, mutect2, varscan2
- CCS | c.285dup p.P96Afs*16 | Frame Shift Ins (INS) | VAF 28/204 reads (14%) | catalogued as rs759691599; called by mutect2, varscan2
- CCT6B | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 52/693 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1469269132; called by muse, mutect2
- CCT6B | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 148/709 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV100031087, COSV58488198; called by muse, mutect2, varscan2
- CD163L1 | c.3545G>T p.R1182M | Missense Mutation (SNP) | VAF 64/430 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV58012256; called by muse, mutect2, varscan2
- CD2BP2 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs550369828, COSV59768758; called by muse, mutect2, varscan2
- CD36 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 105/798 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59214932; called by muse, mutect2, varscan2
- CD44 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 51/415 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868458611; called by muse, mutect2, varscan2
- CD6 | c.741C>A p.H247Q | Missense Mutation (SNP) | VAF 116/532 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.111); catalogued as COSV57839468; called by muse, mutect2
- CD79A | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55740067; called by muse, mutect2, varscan2
- CDC123 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.365); catalogued as COSV55399741; called by muse, mutect2, varscan2
- CDC40 | c.367T>C p.F123L | Missense Mutation (SNP) | VAF 267/938 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1172812863; called by muse, varscan2
- CDC42EP2 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1458473554; called by muse, mutect2, varscan2
- CDCP2 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 128/430 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100313226, COSV61284606; called by muse, mutect2, varscan2
- CDH18 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 139/894 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1031926484, COSV56923155; called by mutect2, varscan2
- CDH4 | c.2605G>T p.D869Y | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64657907; called by muse, mutect2, varscan2
- CDK11A | c.1936A>C p.S646R (on ENST00000378633 / NM_001313896.2; = p.S643R on NM_024011.4) | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1294323462; called by muse, mutect2, varscan2
- CDK15 | c.682C>T p.Q228* (on ENST00000652192 / NM_001366386.2; = p.Q177* on NM_139158.2) | Nonsense Mutation (SNP) | VAF 226/816 reads (28%) | catalogued as COSV99642527; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3986A>G p.Q1329R | Missense Mutation (SNP) | VAF 36/650 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV62573244; called by muse, mutect2
- CDK5RAP3 | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs749650948; called by muse, mutect2, varscan2
- CDRT1 | c.2126G>A p.R709K | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV63054353; called by mutect2, varscan2
- CDRT1 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 186/748 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs746043687, COSV55413444, COSV55413469; called by muse, mutect2, varscan2
- CDS1 | c.617A>G p.H206R | Missense Mutation (SNP) | VAF 255/980 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs747491269; called by muse, mutect2, varscan2
- CEACAM5 | c.1076A>G p.N359S | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs372398696; called by muse, mutect2, varscan2
- CEACAM8 | c.685G>T p.V229F | Missense Mutation (SNP) | VAF 102/297 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.199); catalogued as COSV54990055; called by muse, mutect2, varscan2
- CEBPZ | c.1158A>C p.Q386H | Missense Mutation (SNP) | VAF 304/938 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV99135770; called by mutect2, varscan2
- CENPC | c.406dup p.I136Nfs*4 | Frame Shift Ins (INS) | VAF 216/952 reads (23%) | catalogued as rs755030583; called by mutect2, varscan2
- CENPP | c.379-1G>T p.X127_splice | Splice Site (SNP) | VAF 156/534 reads (29%) | catalogued as COSV65037503; called by muse, varscan2
- CEP170 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 254/1073 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs2993726; called by muse, mutect2, varscan2
- CEP192 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 74/347 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772845551; called by muse, varscan2
- CEP192 | c.5677T>C p.S1893P | Missense Mutation (SNP) | VAF 173/655 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58059965; called by muse, mutect2, varscan2
- CEP290 | c.6283G>T p.D2095Y | Missense Mutation (SNP) | VAF 270/1044 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs778771117; called by muse, mutect2, varscan2
- CEP295 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 237/983 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775885259; called by muse, varscan2
- CEP350 | c.5312G>T p.R1771I | Missense Mutation (SNP) | VAF 62/1430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62609456; called by muse, mutect2
- CEP83 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 108/802 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0.011); catalogued as COSV60410232; called by muse, varscan2
- CERCAM | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs770153869, COSV65711499; called by muse, mutect2, varscan2
- CERS3 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 187/539 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52574041; called by muse, mutect2, varscan2
- CFAP100 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354842659, COSV61503575; called by muse, mutect2, varscan2
- CFAP206 | c.1430dup p.N477Kfs*15 | Frame Shift Ins (INS) | VAF 98/750 reads (13%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP43 | c.4579dup p.S1527Ffs*10 | Frame Shift Ins (INS) | VAF 56/416 reads (13%) | catalogued as rs775645707; called by mutect2, varscan2
- CFAP43 | c.3473G>T p.R1158I | Missense Mutation (SNP) | VAF 48/1336 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV63853150; called by muse, mutect2
- CFAP65 | c.5051G>T p.R1684M | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100445640; called by muse, mutect2, varscan2
- CFAP77 | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV100546183; called by muse, mutect2, varscan2
- CGNL1 | c.1766A>C p.K589T | Missense Mutation (SNP) | VAF 115/905 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs778408718; called by muse, mutect2, varscan2
- CHADL | c.29T>A p.V10D | Missense Mutation (SNP) | VAF 99/404 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); catalogued as rs1247767856; called by muse, mutect2, varscan2
- CHD5 | c.692dup p.Q232Afs*61 | Frame Shift Ins (INS) | VAF 140/462 reads (30%) | catalogued as rs766709340; called by mutect2, varscan2
- CHD7 | c.4882G>A p.G1628R | Missense Mutation (SNP) | VAF 101/433 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs944955791, COSV71113780; called by muse, mutect2, varscan2
- CHD9 | c.7389G>T p.Q2463H (on ENST00000398510 / NM_001382353.1; = p.Q2447H on NM_025134.7) | Missense Mutation (SNP) | VAF 205/738 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV99029428; called by muse, mutect2, varscan2
- CHEK1 | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 118/816 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as rs764708405; called by muse, varscan2
- CHEK2 | c.573G>A p.R191= (on ENST00000382580 / NM_001005735.2; = p.R148= on NM_007194.4) | Splice Region (SNP) | VAF 185/632 reads (29%) | catalogued as rs1298109942; called by muse, mutect2, varscan2
- CHRNB2 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 195/721 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV63809310; called by muse, mutect2, varscan2
- CHST2 | c.1104C>A p.F368L | Missense Mutation (SNP) | VAF 109/833 reads (13%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.867); catalogued as rs564428568; called by muse, mutect2, varscan2
- CHST3 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777166695; called by muse, mutect2, varscan2
- CHST3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 52/379 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs760987231, COSV64151420; called by muse, mutect2, varscan2
- CHST6 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 64/480 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140725711, COSV59999994; called by muse, mutect2, varscan2
- CHST7 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357725037, COSV52099798; called by muse, mutect2, varscan2
- CIC | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 19/411 reads (5%) | catalogued as COSV50696999; called by muse, mutect2
- CIC | c.3347dup p.S1117Kfs*34 | Frame Shift Ins (INS) | VAF 26/182 reads (14%) | catalogued as rs761345552; called by mutect2, varscan2
- CIDEB | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 27/661 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs950306794; called by muse, mutect2
- CIITA | c.1962dup p.G655Rfs*94 | Frame Shift Ins (INS) | VAF 50/172 reads (29%) | catalogued as rs778982759; called by mutect2, varscan2
- CIR1 | c.643T>C p.S215P | Missense Mutation (SNP) | VAF 162/702 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456360880; called by muse, mutect2, varscan2
- CKAP5 | c.2683C>A p.Q895K | Missense Mutation (SNP) | VAF 131/897 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs768861815; called by muse, mutect2, varscan2
- CKS1B | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 115/899 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs775724862; called by muse, mutect2, varscan2
- CLCN4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 54/510 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs184474252, COSV66466815; called by muse, varscan2
- CLCNKB | c.1757-1G>T p.X586_splice | Splice Site (SNP) | VAF 66/628 reads (11%) | catalogued as COSV100989692; called by muse, mutect2, varscan2
- CLDN17 | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 131/927 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs762493404, COSV54524276; called by muse, mutect2, varscan2
- CLDN25 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334266009; called by muse, mutect2, varscan2
- CLEC18B | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 68/654 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1416557817; called by muse, varscan2
- CLEC3A | c.291C>A p.F97L (on ENST00000651443; = p.F88L on NM_005752.6) | Missense Mutation (SNP) | VAF 292/1025 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV55223835; called by muse, mutect2, varscan2
- CLK3 | c.1132G>T p.G378C (on ENST00000395066 / NM_001130028.1; = p.G230C on NM_003992.4) | Missense Mutation (SNP) | VAF 53/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165922; called by muse, varscan2
- CLN6 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 121/418 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as rs1370379616; called by muse, mutect2, varscan2
- CLPX | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 71/636 reads (11%) | catalogued as rs759281371; called by muse, mutect2, varscan2
- CLRN2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 127/467 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); catalogued as COSV101492693; called by muse, mutect2, varscan2
- CLSTN2 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 69/519 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as rs983353407, COSV71720981; called by muse, mutect2, varscan2
- CLSTN3 | c.2858dup p.H954Tfs*163 | Frame Shift Ins (INS) | VAF 86/354 reads (24%) | catalogued as rs758841384; called by mutect2, varscan2
- CLUH | c.3016A>T p.N1006Y (on ENST00000435359; = p.N1045Y on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV70928565; called by muse, mutect2, varscan2
- CLVS1 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 178/816 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100370403, COSV57983897; called by muse, mutect2, varscan2
- CMTR1 | c.265A>G p.S89G | Missense Mutation (SNP) | VAF 71/827 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV65091639; called by muse, mutect2
- CMTR2 | c.1681A>G p.S561G | Missense Mutation (SNP) | VAF 363/1181 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1382707336; called by muse, mutect2, varscan2
- CMTR2 | c.1296dup p.W433Mfs*10 | Frame Shift Ins (INS) | VAF 173/713 reads (24%) | catalogued as rs775222219; called by mutect2, varscan2
- CMYA5 | c.4319A>G p.E1440G | Missense Mutation (SNP) | VAF 258/697 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1207266324; called by muse, mutect2, varscan2
- CNDP2 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 126/417 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs146492497; called by muse, mutect2, varscan2
- CNNM4 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 107/452 reads (24%) | catalogued as COSV100998766; called by muse, mutect2, varscan2
- CNOT1 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 251/953 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs150528737; called by muse, mutect2, varscan2
- CNOT11 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 58/455 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56819527; called by muse, mutect2, varscan2
- CNP | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 90/274 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782472388; called by muse, mutect2, varscan2
- CNTN2 | c.1807C>A p.L603M | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV59349893; called by muse, mutect2, varscan2
- CNTN3 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 75/703 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV55186341; called by muse, mutect2, varscan2
- CNTN5 | c.2857T>C p.Y953H | Missense Mutation (SNP) | VAF 118/748 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV99672567; called by muse, mutect2, varscan2
- CNTNAP1 | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 103/835 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs765899422; called by muse, mutect2, varscan2
- COASY | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV55899827; called by muse, mutect2, varscan2
- COASY | c.701-4C>A | Splice Region (SNP) | VAF 81/296 reads (27%) | catalogued as rs377161549; called by muse, mutect2, varscan2
- COG6 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV62996714; called by muse, mutect2, varscan2
- COG6 | c.1306C>A p.L436I | Missense Mutation (SNP) | VAF 99/577 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV62995973; called by muse, mutect2, varscan2
- COL12A1 | c.7837G>T p.D2613Y | Missense Mutation (SNP) | VAF 94/779 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV104400168; called by muse, mutect2, varscan2
- COL12A1 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 75/490 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); catalogued as rs775010013, COSV59392185; called by muse, mutect2, varscan2
- COL12A1 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 221/778 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs140583215, COSV100486556; called by muse, mutect2, varscan2
- COL17A1 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 69/495 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as COSV62225159; called by muse, mutect2, varscan2
- COL17A1 | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 94/768 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs1176321807; called by muse, mutect2, varscan2
- COL1A1 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs754017100; called by muse, mutect2, varscan2
- COL20A1 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 137/497 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.052); catalogued as rs1204699723; called by muse, mutect2, varscan2
- COL23A1 | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 55/295 reads (19%) | catalogued as COSV66793181; called by muse, mutect2, varscan2
- COL26A1 | c.648dup p.G217Rfs*3 (on ENST00000313669 / NM_001278563.3; = p.G215Rfs*3 on NM_133457.4) | Frame Shift Ins (INS) | VAF 30/271 reads (11%) | catalogued as rs762324149; called by mutect2, varscan2
- COL2A1 | c.2761G>T p.G921C | Missense Mutation (SNP) | VAF 73/568 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM074105, COSV100478050; called by muse, mutect2, varscan2
- COL4A5 | c.2006G>A p.G669D | Missense Mutation (SNP) | VAF 150/567 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM990395; called by mutect2, varscan2
- COL4A6 | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 138/536 reads (26%) | catalogued as COSV57864066; called by muse, mutect2, varscan2
- COL5A2 | c.3604C>T p.R1202* | Nonsense Mutation (SNP) | VAF 61/558 reads (11%) | catalogued as COSV100880869; called by muse, mutect2, varscan2
- COPB2 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 220/875 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as rs745747191, COSV100169028; called by muse, mutect2, varscan2
- COPS9 | c.137-1G>T p.X46_splice (on ENST00000607357 / NM_001163424.2; = p.X77_splice on NM_138336.1) | Splice Site (SNP) | VAF 43/371 reads (12%) | catalogued as COSV56227690; called by muse, mutect2, varscan2
- CPED1 | c.2733G>T p.Q911H | Missense Mutation (SNP) | VAF 154/561 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60002253; called by muse, mutect2, varscan2
- CPHXL | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 173/1172 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.093); catalogued as rs1474477528; called by muse, mutect2, varscan2
- CPSF2 | c.1614A>G p.I538M | Missense Mutation (SNP) | VAF 88/392 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54100107; called by muse, mutect2, varscan2
- CRACD | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51718557, COSV99948870; called by muse, mutect2, varscan2
- CRISP3 | c.455A>G p.N152S (on ENST00000371159 / NM_001368123.1; = p.N134S on NM_006061.4) | Missense Mutation (SNP) | VAF 299/1086 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs559738360; called by muse, mutect2, varscan2
- CROCC | c.3735G>T p.Q1245H | Missense Mutation (SNP) | VAF 60/648 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65012436; called by muse, mutect2
- CRYBG2 | c.2505G>T p.E835D | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs372782133; called by muse, mutect2, varscan2
- CRYBG2 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs1260391246; called by muse, mutect2, varscan2
- CRYGA | c.476dup p.A160Cfs*29 | Frame Shift Ins (INS) | VAF 54/410 reads (13%) | catalogued as rs762650691; called by mutect2, varscan2
- CSMD1 | c.6258G>T p.Q2086H (on ENST00000520002; = p.Q2085H on NM_033225.6) | Missense Mutation (SNP) | VAF 196/600 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs768046798, COSV59349456; called by muse, mutect2, varscan2
- CSMD3 | c.6014G>A p.R2005K (on ENST00000297405 / NM_001363185.1; = p.R1901K on NM_052900.3) | Missense Mutation (SNP) | VAF 151/886 reads (17%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.484); catalogued as COSV52281828; called by muse, mutect2, varscan2
- CTAGE6 | c.1146G>T p.Q382H | Missense Mutation (SNP) | VAF 46/552 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV101417836; called by muse, mutect2
- CTC1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as rs753797185, COSV58983930; called by muse, mutect2, varscan2
- CTNNA2 | c.2851G>A p.D951N (on ENST00000402739 / NM_001282597.3; = p.D903N on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 189/651 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV100561432, COSV58161036; called by muse, mutect2, varscan2
- CTNNB1 | c.616A>G p.N206D | Missense Mutation (SNP) | VAF 261/904 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1463690576, COSV62692725, COSV62696679; called by muse, mutect2, varscan2
- CTSH | c.549G>A p.G183= | Splice Region (SNP) | VAF 36/154 reads (23%) | catalogued as rs746828205; called by muse, mutect2, varscan2
- CTSO | c.396C>A p.C132* | Nonsense Mutation (SNP) | VAF 132/511 reads (26%) | catalogued as COSV70809129, COSV70809517; called by muse, mutect2, varscan2
- CUBN | c.10009T>G p.L3337V | Missense Mutation (SNP) | VAF 76/626 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.646); catalogued as COSV100913865; called by muse, mutect2, varscan2
- CUL7 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756674731; called by muse, mutect2, varscan2
- CUL9 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.926); catalogued as COSV52726332; called by muse, mutect2, varscan2
- CUX2 | c.4451G>T p.W1484L | Missense Mutation (SNP) | VAF 76/329 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55650818; called by muse, mutect2, varscan2
- CUZD1 | c.1640G>T p.S547I | Missense Mutation (SNP) | VAF 159/1056 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as rs1566228858; called by muse, mutect2, varscan2
- CXCR6 | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 53/393 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs748198143; called by muse, mutect2, varscan2
- CXXC5 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs539925906; called by muse, mutect2, varscan2
- CYP19A1 | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 78/652 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as COSV53058449; called by muse, varscan2
- CYP26B1 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 99/320 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1419156117; called by muse, mutect2, varscan2
- CYP7B1 | c.650dup p.L217Ffs*4 | Frame Shift Ins (INS) | VAF 112/528 reads (21%) | catalogued as rs1298132281; called by mutect2, varscan2
- CYTH1 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 80/401 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739397; called by muse, mutect2, varscan2
- DACH1 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 103/524 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57495760; called by muse, mutect2, varscan2
- DAP3 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 84/648 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100546673; called by muse, mutect2, varscan2
- DAW1 | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 34/1178 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as COSV59368817; called by muse, mutect2
- DBT | c.788T>C p.M263T | Missense Mutation (SNP) | VAF 162/493 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553230703, CM062576, CM093780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCBLD2 | c.467A>G p.H156R | Missense Mutation (SNP) | VAF 131/838 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs771411018; called by muse, mutect2, varscan2
- DCC | c.3215G>T p.R1072I | Missense Mutation (SNP) | VAF 206/717 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as rs866701043; called by muse, mutect2, varscan2
- DCDC1 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 157/1011 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376440811, COSV100663334; called by muse, varscan2
- DCLK3 | c.327dup p.R110Qfs*21 | Frame Shift Ins (INS) | VAF 56/378 reads (15%) | catalogued as rs1439955533; called by mutect2, varscan2
- DCN | c.325-1G>T p.X109_splice | Splice Site (SNP) | VAF 134/795 reads (17%) | catalogued as COSV99271942; called by muse, mutect2, varscan2
- DDHD1 | c.1328G>T p.G443V (on ENST00000323669; = p.G640V on NM_030637.3) | Missense Mutation (SNP) | VAF 282/861 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV60358047; called by muse, mutect2, varscan2
- DDX1 | c.1448-1G>T p.X483_splice | Splice Site (SNP) | VAF 56/433 reads (13%) | catalogued as COSV51844193; called by muse, mutect2, varscan2
- DDX18 | c.1040T>C p.L347S | Missense Mutation (SNP) | VAF 126/831 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54306035; called by muse, mutect2, varscan2
- DDX20 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 285/1023 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs377532506; called by muse, mutect2, varscan2
- DDX4 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 122/691 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61756511; called by muse, mutect2, varscan2
- DDX54 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 120/462 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58371844; called by muse, mutect2, varscan2
- DDX60 | c.3947C>T p.A1316V | Missense Mutation (SNP) | VAF 252/938 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746913587, COSV67097536; called by mutect2, varscan2
- DDX60 | c.119dup p.L40Ffs*3 | Frame Shift Ins (INS) | VAF 253/896 reads (28%) | catalogued as rs763030135; called by mutect2, varscan2
- DDX60L | c.3089T>G p.L1030W | Missense Mutation (SNP) | VAF 22/610 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52712768; called by muse, mutect2
- DENND2C | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 256/885 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs370489313; called by muse, mutect2, varscan2
- DENND4B | c.304dup p.L102Pfs*3 | Frame Shift Ins (INS) | VAF 76/512 reads (15%) | catalogued as rs747842790; called by mutect2, varscan2
- DENND5A | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 102/735 reads (14%) | catalogued as rs1554919092, COSV60236055; called by muse, varscan2
- DEPTOR | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 74/431 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); catalogued as rs775850799; called by muse, mutect2, varscan2
- DERL2 | c.238C>A p.R80S | Missense Mutation (SNP) | VAF 178/800 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50148031; called by muse, mutect2, varscan2
- DIAPH1 | c.2206C>A p.P736T | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs1637814; called by muse, mutect2, varscan2
- DIAPH3 | c.3055dup p.R1019Kfs*14 (on ENST00000400324 / NM_001042517.2; = p.R756Kfs*14 on NM_030932.3) | Frame Shift Ins (INS) | VAF 104/456 reads (23%) | catalogued as rs753024929; called by mutect2, varscan2
- DICER1 | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 132/886 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.831); catalogued as CD166013, COSV58615675; called by muse, mutect2, varscan2
- DKK1 | c.633A>C p.K211N | Missense Mutation (SNP) | VAF 129/1005 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64760606; called by muse, mutect2, varscan2
- DLD | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 49/1439 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52737880; called by muse, mutect2
- DLG2 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 104/720 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs757243832; called by muse, varscan2
- DMPK | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs1406955459; called by muse, mutect2, varscan2
- DMTF1 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 150/1099 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs1346839614; called by muse, mutect2, varscan2
- DNAAF1 | c.1214G>T p.R405I | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100533798; called by muse, mutect2, varscan2
- DNAH10 | c.8668C>A p.L2890M (on ENST00000409039; = p.L2829M on NM_207437.3) | Missense Mutation (SNP) | VAF 23/620 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1421018509; called by muse, mutect2
- DNAH10 | c.12160C>A p.L4054M (on ENST00000409039; = p.L3993M on NM_207437.3) | Missense Mutation (SNP) | VAF 57/616 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs201458422; called by muse, mutect2
- DNAH12 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 85/619 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1215843178; called by muse, mutect2, varscan2
- DNAH17 | c.4421G>A p.S1474N | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.132); catalogued as COSV67762072; called by muse, mutect2, varscan2
- DNAH2 | c.13075C>T p.L4359F | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as rs746025464; called by muse, mutect2, varscan2
- DNAH6 | c.4973C>A p.S1658Y | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200389898, COSV104378629; called by muse, mutect2, varscan2
- DNAH8 | c.2485G>T p.D829Y | Missense Mutation (SNP) | VAF 137/488 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV59457156; called by muse, mutect2, varscan2
- DNAH8 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 140/868 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as rs756385686; called by muse, mutect2, varscan2
- DNAH9 | c.583dup p.M195Nfs*9 | Frame Shift Ins (INS) | VAF 194/708 reads (27%) | catalogued as rs754168239; called by mutect2, varscan2
- DNAH9 | c.3036G>T p.Q1012H | Missense Mutation (SNP) | VAF 145/479 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52377659; called by muse, mutect2, varscan2
- DNAH9 | c.5098A>G p.T1700A | Missense Mutation (SNP) | VAF 104/697 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1439320324; called by muse, mutect2, varscan2
- DNAH9 | c.8893C>A p.R2965S | Missense Mutation (SNP) | VAF 192/736 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52335061; called by muse, varscan2
- DNAJB7 | c.884dup p.K296Efs*3 | Frame Shift Ins (INS) | VAF 288/986 reads (29%) | catalogued as rs768619916; called by mutect2, varscan2
- DNAJC10 | c.1314G>T p.K438N | Missense Mutation (SNP) | VAF 68/504 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV51142051; called by muse, mutect2, varscan2
- DNM3 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 96/745 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV62468524; called by muse, mutect2, varscan2
- DOCK10 | c.5954T>C p.L1985P | Missense Mutation (SNP) | VAF 31/731 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.573); catalogued as rs1173977206; called by muse, mutect2
- DOCK3 | c.1541-1G>A p.X514_splice | Splice Site (SNP) | VAF 96/297 reads (32%) | catalogued as COSV56546940; called by muse, mutect2, varscan2
- DOCK3 | c.3610A>C p.R1204= | Splice Region (SNP) | VAF 32/282 reads (11%) | catalogued as rs1346229149; called by muse, mutect2, varscan2
- DOCK3 | c.3611G>T p.R1204M | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56516967; called by muse, mutect2, varscan2
- DOCK7 | c.1408A>G p.T470A | Missense Mutation (SNP) | VAF 121/921 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV52007029; called by muse, mutect2, varscan2
- DOLK | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.303); catalogued as COSV58281531; called by muse, mutect2, varscan2
- DOP1B | c.6744G>T p.M2248I | Missense Mutation (SNP) | VAF 107/763 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV67690847; called by muse, mutect2, varscan2
- DPRX | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 63/443 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs143612661, COSV64949465; called by muse, mutect2, varscan2
- DRD2 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199577077; called by muse, mutect2, varscan2
- DRICH1 | c.644-1G>T p.X215_splice | Splice Site (SNP) | VAF 99/598 reads (17%) | catalogued as rs1252996551; called by muse, mutect2, varscan2
- DSC2 | c.2398dup p.A800Gfs*37 | Frame Shift Ins (INS) | VAF 74/465 reads (16%) | catalogued as rs397517399; ClinVar: uncertain significance; called by mutect2, varscan2
- DSCAM | c.3520G>A p.G1174R | Missense Mutation (SNP) | VAF 52/1136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1332241663, COSV68027539; called by muse, mutect2
- DTHD1 | c.550G>A p.V184M (on ENST00000456874; = p.V19M on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 181/1135 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs781680006; called by muse, mutect2, varscan2
- DTX2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 101/403 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1485456056, COSV100184890; called by muse, mutect2, varscan2
- DTX3 | c.433del p.L145Cfs*51 | Frame Shift Del (DEL) | VAF 21/173 reads (12%) | catalogued as rs758962538; called by mutect2, varscan2
- DUOX1 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 56/527 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as rs762923757, COSV58480029; called by muse, mutect2, varscan2
- DUOX2 | c.3266G>A p.S1089N | Missense Mutation (SNP) | VAF 23/496 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1209325338; called by muse, mutect2
- DUS3L | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs150467937; called by muse, mutect2, varscan2
- DUSP18 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 21/469 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as rs1412294357; called by muse, mutect2
- DVL2 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 180/610 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs148130258; called by muse, mutect2, varscan2
- DYNC1H1 | c.10078A>G p.S3360G | Missense Mutation (SNP) | VAF 195/629 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as CM1510057; called by muse, mutect2, varscan2
- DYNC2H1 | c.5584T>G p.Y1862D | Missense Mutation (SNP) | VAF 125/1083 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370857674; called by muse, mutect2, varscan2
- DYSF | c.2248C>A p.Q750K | Missense Mutation (SNP) | VAF 145/512 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs1027145211, CM116704; called by muse, mutect2, varscan2
- DZIP1 | c.1996G>T p.D666Y (on ENST00000347108; = p.D647Y on NM_014934.5) | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs773186628; called by muse, mutect2, varscan2
- EBLN1 | c.494T>A p.F165Y | Missense Mutation (SNP) | VAF 139/1015 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV69370141; called by muse, mutect2, varscan2
- EEPD1 | c.1334T>A p.I445N | Missense Mutation (SNP) | VAF 69/534 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV54197314; called by muse, mutect2, varscan2
- EFCAB13 | c.500A>G p.H167R | Missense Mutation (SNP) | VAF 61/576 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs769045530; called by muse, mutect2, varscan2
- EFCAB13 | c.1380C>A p.F460L | Missense Mutation (SNP) | VAF 86/686 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV58947083; called by muse, mutect2, varscan2
- EFCAB5 | c.3564G>T p.E1188D | Missense Mutation (SNP) | VAF 184/622 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs774908882; called by muse, mutect2, varscan2
- EFCAB6 | c.3341dup p.L1114Ffs*22 | Frame Shift Ins (INS) | VAF 166/645 reads (26%) | catalogued as rs934565712; called by mutect2, varscan2
- EFNB1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM111715; called by muse, mutect2, varscan2
- EGFLAM | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 221/668 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.816); catalogued as rs1334328207; called by muse, mutect2, varscan2
- EGFLAM | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 215/631 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148322152, COSV59311196; called by muse, mutect2, varscan2
- EHMT2 | c.2350G>T p.G784W | Missense Mutation (SNP) | VAF 159/530 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64994591; called by muse, mutect2, varscan2
- EIF4B | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 164/677 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV100016758; called by muse, mutect2, varscan2
- ELMOD2 | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 76/749 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.543); catalogued as rs755163165; called by muse, mutect2, varscan2
- ELP2 | c.1997C>A p.S666Y | Missense Mutation (SNP) | VAF 108/922 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1449909744, COSV60853150; called by muse, mutect2, varscan2
- EMC1 | c.1945-2A>G p.X649_splice | Splice Site (SNP) | VAF 62/742 reads (8%) | catalogued as rs548721532; called by muse, mutect2
- EMC1 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 250/824 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61886913; called by muse, mutect2, varscan2
- EMILIN1 | c.1353dup p.L452Afs*57 | Frame Shift Ins (INS) | VAF 33/252 reads (13%) | catalogued as rs763633527; called by mutect2, varscan2
- EMILIN2 | c.2167C>A p.L723I | Missense Mutation (SNP) | VAF 52/413 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.666); catalogued as COSV54422784; called by muse, mutect2, varscan2
- EMILIN2 | c.2572G>A p.G858S | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as rs1319208391; called by muse, mutect2, varscan2
- EN1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1353949615; called by muse, mutect2, varscan2
- ENAH | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.986); catalogued as rs777614159, COSV52865332; called by muse, mutect2, varscan2
- ENAM | c.1139A>G p.H380R | Missense Mutation (SNP) | VAF 141/458 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113185287; called by muse, mutect2, varscan2
- ENDOV | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 132/508 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1057228950; called by muse, mutect2, varscan2
- ENKUR | c.211dup p.T71Nfs*9 | Frame Shift Ins (INS) | VAF 170/582 reads (29%) | catalogued as rs1378928147; called by mutect2, varscan2
- ENO3 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 136/463 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.498); catalogued as rs151067614; called by muse, mutect2, varscan2
- ENO4 | c.1759dup p.Y587Lfs*3 (on ENST00000622726; = p.Y584Lfs*3 on NM_001242699.2) | Frame Shift Ins (INS) | VAF 164/584 reads (28%) | catalogued as rs763733545; called by mutect2, varscan2
- ENPEP | c.846G>T p.M282I | Missense Mutation (SNP) | VAF 92/640 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs780020784; called by mutect2, varscan2
- ENPEP | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 169/1092 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.018); catalogued as COSV54458718; called by muse, mutect2, varscan2
- ENPP1 | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 252/1028 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.371); catalogued as rs776716141; called by muse, mutect2, varscan2
- EP300 | c.6970dup p.H2324Pfs*55 | Frame Shift Ins (INS) | VAF 34/186 reads (18%) | catalogued as rs754418509; called by mutect2, varscan2
- EPHA7 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 281/1108 reads (25%) | catalogued as rs1300929218, COSV100992397, COSV65169176; called by muse, mutect2, varscan2
- EPHB2 | c.2955G>A p.E985= (on ENST00000400191 / NM_001309193.2; = p.E986= on NM_004442.7) | Splice Region (SNP) | VAF 106/442 reads (24%) | catalogued as rs1190197177; called by muse, mutect2, varscan2
- EPPIN | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 179/707 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as COSV51491707; called by muse, mutect2, varscan2
- EPPK1 | c.6428A>T p.Y2143F | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as COSV73261473; called by muse, mutect2, varscan2
- ERF | c.880C>G p.P294A | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as rs1345473113; called by muse, mutect2, varscan2
- ERMP1 | c.2168C>T p.T723I | Missense Mutation (SNP) | VAF 218/779 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as rs1378096672; called by muse, mutect2, varscan2
- ERO1A | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs753901014; called by muse, mutect2, varscan2
- ESPNL | c.1243A>T p.T415S | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs772635545; called by muse, mutect2, varscan2
- ESRP1 | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 78/339 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.465); catalogued as COSV64412019; called by muse, mutect2, varscan2
- ETFRF1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 145/1226 reads (12%) | catalogued as COSV61477538; called by muse, mutect2, varscan2
- EXPH5 | c.5503C>A p.L1835I | Missense Mutation (SNP) | VAF 120/879 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99761208; called by muse, mutect2, varscan2
- EYA1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs200923204, CM085391, COSV58157220; called by muse, mutect2, varscan2
- EZH2 | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 184/1100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57446595; called by muse, varscan2
- EZHIP | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV57955174; called by muse, mutect2, varscan2
- F11 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 302/1019 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as rs909066270; called by muse, mutect2, varscan2
- F13A1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 125/440 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776782223, COSV99342697; called by muse, mutect2, varscan2
- F2 | c.423-1G>T p.X141_splice | Splice Site (SNP) | VAF 16/110 reads (15%) | catalogued as COSV100319250; called by mutect2, varscan2
- F5 | c.2603C>A p.P868H | Missense Mutation (SNP) | VAF 78/606 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1041753299, COSV100889224; called by muse, mutect2, varscan2
- F5 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 250/774 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295008658; called by muse, mutect2, varscan2
- FADS3 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as rs945361268; called by muse, mutect2, varscan2
- FAH | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 60/564 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55722618; called by muse, mutect2
- FAM111A | c.640T>C p.Y214H | Missense Mutation (SNP) | VAF 288/975 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs752786340; called by muse, mutect2, varscan2
- FAM120B | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 95/697 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1203344771, COSV53002747; called by muse, mutect2, varscan2
- FAM120B | c.2440T>C p.Y814H | Missense Mutation (SNP) | VAF 230/869 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs918030400; called by muse, mutect2, varscan2
- FAM133A | c.271dup p.R91Kfs*22 | Frame Shift Ins (INS) | VAF 348/1214 reads (29%) | catalogued as rs1358655811; called by mutect2, varscan2
- FAM149A | c.2156A>G p.H719R (on ENST00000356371 / NM_001367768.2; = p.H428R on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/842 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753158650; called by muse, mutect2, varscan2
- FAM172A | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 120/740 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67940180; called by mutect2, varscan2
- FAM174C | c.399A>G p.*133Wext*2 | Nonstop Mutation (SNP) | VAF 24/155 reads (15%) | catalogued as rs1483412463; called by muse, mutect2, varscan2
- FAM186B | c.2069G>T p.S690I | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs765872651; called by muse, mutect2, varscan2
- FAM200A | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 149/1065 reads (14%) | catalogued as rs1159631601, COSV101282709; called by muse, mutect2, varscan2
- FAM71C | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 126/896 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as COSV100175813; called by muse, varscan2
- FAM83B | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 253/915 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759117235, COSV60920258; called by muse, mutect2, varscan2
- FAN1 | c.2090G>T p.R697I | Missense Mutation (SNP) | VAF 227/851 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs749900780, COSV62951391; called by muse, mutect2, varscan2
- FANCD2 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 292/1199 reads (24%) | catalogued as COSV55039053; called by muse, mutect2, varscan2
- FAP | c.1620-2A>G p.X540_splice | Splice Site (SNP) | VAF 131/496 reads (26%) | catalogued as COSV51859168; called by muse, mutect2, varscan2
- FASN | c.4537dup p.A1513Gfs*13 | Frame Shift Ins (INS) | VAF 92/292 reads (32%) | catalogued as rs996569586; called by mutect2, varscan2
- FAT2 | c.10178C>A p.S3393Y | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV55822628; called by muse, mutect2, varscan2
- FAT3 | c.12592G>T p.A4198S | Missense Mutation (SNP) | VAF 69/510 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.516); catalogued as COSV53086783; called by muse, mutect2, varscan2
- FAT4 | c.5594C>T p.A1865V | Missense Mutation (SNP) | VAF 116/977 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58708860; called by muse, mutect2, varscan2
- FBLN2 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 146/476 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as rs534802167, COSV55486389; called by muse, mutect2
- FBLN5 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 214/760 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs771425892; called by muse, mutect2, varscan2
- FBN2 | c.7659dup p.F2554Vfs*4 | Frame Shift Ins (INS) | VAF 164/836 reads (20%) | catalogued as rs748600284; called by mutect2, varscan2
- FBXL8 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773252872; called by muse, mutect2, varscan2
- FBXO27 | c.767G>C p.R256P | Missense Mutation (SNP) | VAF 84/342 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV53072317, COSV99494717; called by muse, mutect2, varscan2
- FBXO8 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 243/882 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.535); catalogued as rs1468499707, COSV67031893; called by muse, mutect2, varscan2
- FBXW8 | c.764T>C p.V255A (on ENST00000309909; = p.V293A on NM_012174.1) | Missense Mutation (SNP) | VAF 68/597 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as rs1180624125; called by muse, mutect2, varscan2
- FCGR3A | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 167/1261 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs769053373; called by muse, mutect2, varscan2
- FCGR3B | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 135/909 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV54209245, COSV54210810; called by muse, mutect2, varscan2
- FCRL2 | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 122/433 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV63833220; called by muse, mutect2, varscan2
- FGD1 | c.1448C>T p.T483I | Missense Mutation (SNP) | VAF 28/748 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV64308776; called by muse, mutect2
- FHDC1 | c.153G>T p.R51S | Missense Mutation (SNP) | VAF 130/476 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV52599280; called by muse, mutect2, varscan2
- FHOD1 | c.1220C>A p.P407H | Missense Mutation (SNP) | VAF 67/573 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99264542; called by muse, mutect2, varscan2
- FIZ1 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs770628681; called by muse, mutect2, varscan2
- FLCN | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 56/402 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1363880753, COSV53257232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG2 | c.5012G>A p.G1671E | Missense Mutation (SNP) | VAF 70/417 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs752892733; called by muse, mutect2, varscan2
- FLNC | c.4569G>T p.E1523D | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as rs1292246444; called by muse, mutect2, varscan2
- FLRT3 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 299/925 reads (32%) | catalogued as COSV54039664; called by muse, mutect2, varscan2
- FMN1 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs189215270; called by muse, mutect2, varscan2
- FMN2 | c.5094G>T p.K1698N | Missense Mutation (SNP) | VAF 227/950 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV60442517; called by muse, mutect2, varscan2
- FNIP1 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 203/613 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV57196696; called by muse, mutect2, varscan2
- FOSB | c.127-1G>T p.X43_splice | Splice Site (SNP) | VAF 27/93 reads (29%) | catalogued as COSV100798809; called by muse, mutect2, varscan2
- FREM3 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs756887319; called by muse, mutect2, varscan2
- FRMPD1 | c.2410G>T p.A804S | Missense Mutation (SNP) | VAF 87/694 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV66701901; called by muse, mutect2, varscan2
- FSIP2 | c.8038dup p.T2680Nfs*9 | Frame Shift Ins (INS) | VAF 356/1262 reads (28%) | catalogued as rs755234663; called by mutect2, varscan2
- FSIP2 | c.18013A>G p.T6005A | Missense Mutation (SNP) | VAF 231/923 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV58078012; called by muse, mutect2, varscan2
- FUBP1 | c.1579A>G p.K527E | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV53933428; called by muse, mutect2, varscan2
- FUT11 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 78/484 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100227014; called by muse, mutect2, varscan2
- FYB2 | c.1851dup p.E618Rfs*6 | Frame Shift Ins (INS) | VAF 312/1080 reads (29%) | catalogued as rs751048223; called by mutect2, varscan2
- FZD7 | c.575C>A p.A192E | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV53811359; called by muse, varscan2
- GAA | c.2408A>G p.Q803R | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs142487534, CD120542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAB1 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 143/531 reads (27%) | catalogued as rs1458245713, COSV53754258; called by muse, mutect2, varscan2
- GABARAPL1 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 186/816 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs751714337; called by muse, varscan2
- GABRG1 | c.839C>A p.P280Q | Missense Mutation (SNP) | VAF 308/1009 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54962532; called by muse, mutect2, varscan2
- GABRG2 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 68/455 reads (15%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV62717905; called by muse, mutect2, varscan2
- GAL3ST3 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 97/326 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV61748894; called by muse, mutect2, varscan2
- GALNT3 | c.1102dup p.S368Ffs*8 | Frame Shift Ins (INS) | VAF 227/1030 reads (22%) | catalogued as rs1169338996; called by mutect2, varscan2
- GALNTL6 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 102/976 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151281441, COSV72493955; called by muse, mutect2, varscan2
- GAREM1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 57/456 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.771); catalogued as COSV52514129; called by muse, mutect2, varscan2
- GARRE1 | c.2390A>G p.Y797C | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.874); catalogued as rs200076215; called by muse, mutect2, varscan2
- GAS6 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs747484336; called by muse, mutect2, varscan2
- GATA6 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1428539753; called by muse, mutect2, varscan2
- GCN1 | c.4586C>A p.P1529H | Missense Mutation (SNP) | VAF 128/484 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100325209; called by muse, mutect2
- GCN1 | c.881A>G p.Q294R | Missense Mutation (SNP) | VAF 141/533 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs773737328; called by muse, mutect2, varscan2
- GCNT2 | c.392A>G p.K131R | Missense Mutation (SNP) | VAF 243/821 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV65458084; called by muse, mutect2, varscan2
- GCNT4 | c.1297A>G p.R433G | Missense Mutation (SNP) | VAF 128/835 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs753522564; called by muse, mutect2, varscan2
- GDF11 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 186/608 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as rs756132179; called by muse, varscan2
- GDF7 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs1171286439; called by muse, mutect2, varscan2
- GDF9 | c.830G>T p.S277I | Missense Mutation (SNP) | VAF 171/506 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99736975; called by muse, mutect2, varscan2
- GDPD5 | c.1109G>A p.S370N | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.049); catalogued as COSV61126998; called by muse, mutect2, varscan2
- GFAP | c.1419A>T p.*473Cext*33 (on ENST00000253408 / NM_001363846.2; = p.*433Cext*33 on NM_002055.5) | Nonstop Mutation (SNP) | VAF 49/351 reads (14%) | catalogued as CX124977; called by muse, mutect2, varscan2
- GIGYF1 | c.1869-2A>G p.X623_splice | Splice Site (SNP) | VAF 20/176 reads (11%) | catalogued as rs112316639; called by mutect2, varscan2
- GINS3 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 264/968 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV58920406; called by muse, mutect2, varscan2
- GJB5 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV58357288; called by muse, varscan2
- GLA | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 150/591 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as CM012368; called by muse, mutect2, varscan2
- GLI2 | c.2470C>A p.L824M (on ENST00000361492 / NM_001374353.1; = p.L841M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.202); catalogued as rs759692739; called by muse, varscan2
- GLIS2 | c.1190dup p.M398Hfs*69 | Frame Shift Ins (INS) | VAF 44/166 reads (27%) | catalogued as rs746968228; called by mutect2, varscan2
- GLS2 | c.910A>G p.M304V | Missense Mutation (SNP) | VAF 247/946 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568280019; called by muse, varscan2
- GLUD1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 145/410 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs777627931, COSV99518331; called by muse, mutect2, varscan2
- GLYAT | c.317-2A>G p.X106_splice | Splice Site (SNP) | VAF 44/285 reads (15%) | catalogued as rs772600587; called by muse, mutect2, varscan2
- GNAS | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 312/974 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV99670729; called by muse, mutect2, varscan2
- GOLGA3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 58/487 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs138174554; called by muse, mutect2, varscan2
- GOLM2 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 118/458 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs138401571; called by muse, mutect2, varscan2
- GPA33 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 208/710 reads (29%) | catalogued as COSV100901314; called by muse, mutect2, varscan2
- GPATCH8 | c.3068G>A p.R1023Q | Missense Mutation (SNP) | VAF 94/376 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100132398; called by muse, mutect2
- GPC3 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 117/876 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV63670042; called by muse, mutect2, varscan2
- GPCPD1 | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 102/806 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs141984830; called by muse, mutect2, varscan2
- GPR153 | c.1705T>C p.W569R | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as rs1278987490; called by muse, mutect2, varscan2
- GPR158 | c.3428dup p.T1144Dfs*5 | Frame Shift Ins (INS) | VAF 226/792 reads (29%) | catalogued as rs760000398; called by mutect2, varscan2
- GPR19 | c.754A>G p.R252G | Missense Mutation (SNP) | VAF 257/891 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100196980; called by muse, mutect2, varscan2
- GPR84 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766899348, COSV57210025; called by mutect2, varscan2
- GPRC5B | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56029092; called by muse, mutect2
- GPS2 | c.804A>G p.S268= | Splice Region (SNP) | VAF 111/532 reads (21%) | catalogued as rs769364819; called by muse, mutect2, varscan2
- GRB10 | c.1371G>T p.E457D (on ENST00000398812; = p.E411D on NM_001001549.3) | Missense Mutation (SNP) | VAF 169/600 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100241360, COSV60010006; called by muse, mutect2, varscan2
- GRHL1 | c.1591+2T>G p.X531_splice | Splice Site (SNP) | VAF 111/401 reads (28%) | catalogued as COSV104411925; called by muse, varscan2
- GRIA1 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 116/656 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs776115991, COSV53618574; called by muse, varscan2
- GRK3 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 248/933 reads (27%) | catalogued as COSV60797585; called by muse, mutect2, varscan2
- GRN | c.600G>T p.V200= | Splice Region (SNP) | VAF 75/224 reads (33%) | catalogued as COSV50008740; called by muse, mutect2, varscan2
- GSDME | c.632T>C p.I211T | Missense Mutation (SNP) | VAF 64/420 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs1447128319; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1306T>C p.Y436H | Missense Mutation (SNP) | VAF 64/797 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1554454440; called by muse, mutect2
- GTF3C1 | c.5541dup p.E1848Rfs*22 | Frame Shift Ins (INS) | VAF 48/188 reads (26%) | catalogued as rs763161381; called by mutect2, varscan2
- GTSE1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 118/448 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV71889360; called by muse, mutect2, varscan2
- GTSE1 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 59/568 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.137); catalogued as rs747026610, COSV71889050, COSV71889400; called by muse, mutect2, varscan2
- GUCA1A | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 127/470 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV50004543; called by muse, mutect2, varscan2
- HABP4 | c.445A>G p.R149G | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs767411366; called by muse, varscan2
- HADHA | c.1367A>G p.H456R | Missense Mutation (SNP) | VAF 182/689 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1375455111; called by muse, mutect2, varscan2
- HADHA | c.374G>T p.R125I | Missense Mutation (SNP) | VAF 32/902 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV66107228; called by muse, mutect2
- HADHB | c.1389+2T>C p.X463_splice | Splice Site (SNP) | VAF 90/348 reads (26%) | catalogued as rs760513370; called by muse, mutect2, varscan2
- HBD | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 112/944 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs34420481; called by muse, varscan2
- HCAR3 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 54/436 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.155); catalogued as rs759506084; called by muse, mutect2, varscan2
- HDAC3 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 166/501 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV59496706; called by muse, mutect2, varscan2
- HECTD4 | c.11937C>A p.F3979L | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs763092592; called by muse, mutect2, varscan2
- HEMK1 | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV51750990; called by muse, mutect2
- HEPHL1 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 115/811 reads (14%) | catalogued as COSV59895692; called by muse, mutect2, varscan2
- HERC1 | c.12797-4dup | Splice Region (INS) | VAF 124/558 reads (22%) | catalogued as rs762777172; called by mutect2, varscan2
- HERC1 | c.3916C>T p.R1306C | Missense Mutation (SNP) | VAF 150/1208 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs1475134003, COSV101496506; called by muse, mutect2, varscan2
- HERC2 | c.10423T>A p.S3475T | Missense Mutation (SNP) | VAF 144/633 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs756124565; called by muse, mutect2, varscan2
- HFE | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 295/1057 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183193280; called by muse, mutect2, varscan2
- HHIP | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 125/938 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs759006205, COSV104409587; called by muse, mutect2, varscan2
- HIVEP2 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 146/462 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs766027883, COSV50006105, COSV50045049; called by muse, mutect2, varscan2
- HLA-DPB1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 122/329 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as CM074901; called by muse, mutect2, varscan2
- HLTF | c.2170A>G p.N724D | Missense Mutation (SNP) | VAF 98/830 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1260580509; called by muse, mutect2, varscan2
- HLTF | c.1893G>A p.R631= | Splice Region (SNP) | VAF 24/609 reads (4%) | catalogued as rs1264909194, COSV59501078; called by muse, mutect2
- HMCN2 | c.9163G>T p.G3055W | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71815423; called by muse, mutect2, varscan2
- HMGB1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.226); catalogued as rs1467491356; called by mutect2, varscan2
- HMOX1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.11); catalogued as rs963351011, COSV53340609; called by muse, mutect2, varscan2
- HNF4A | c.1415A>G p.E472G | Missense Mutation (SNP) | VAF 56/560 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as COSV100291288; called by muse, mutect2, varscan2
- HNRNPCL3 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs1368768219; called by mutect2, varscan2
- HNRNPUL2 | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 139/461 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375522245; called by muse, mutect2, varscan2
- HOOK1 | c.1391G>T p.R464M | Missense Mutation (SNP) | VAF 134/537 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100969246; called by muse, mutect2, varscan2
- HOXC9 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 29/232 reads (13%) | catalogued as COSV57716424; called by muse, mutect2, varscan2
- HSDL2 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 263/959 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV52714035, COSV99357026; called by muse, mutect2, varscan2
- HSPG2 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 156/522 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1386810012; called by muse, mutect2, varscan2
- HSPH1 | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 140/672 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs745748060; called by muse, mutect2, varscan2
- HTR1B | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as rs776215353; called by muse, mutect2, varscan2
- HTR2C | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 118/877 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52224663; called by muse, mutect2, varscan2
- HTR3A | c.917-1G>T p.X306_splice | Splice Site (SNP) | VAF 86/376 reads (23%) | catalogued as COSV55470539; called by muse, varscan2
- HUWE1 | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 91/838 reads (11%) | catalogued as COSV99472771; called by muse, mutect2, varscan2
- HUWE1 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 102/848 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53336302; called by muse, mutect2, varscan2
- HYDIN | c.13673G>A p.G4558D | Missense Mutation (SNP) | VAF 106/393 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1289897852; called by muse, mutect2, varscan2
- HYDIN | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 95/725 reads (13%) | catalogued as rs867513811; called by muse, mutect2, varscan2
- HYKK | c.803T>C p.I268T | Missense Mutation (SNP) | VAF 27/659 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1487001398; called by muse, mutect2
- ICA1 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 104/846 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV99655714; called by muse, mutect2, varscan2
- ICAM4 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs35713817, COSV99320521; called by muse, mutect2, varscan2
- ICAM5 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1475171779; called by muse, mutect2, varscan2
- ID4 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1261039329; called by muse, mutect2, varscan2
- IFI35 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 100/422 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs149614000; called by muse, mutect2, varscan2
- IFNAR2 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 90/898 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577150, COSV59750892; called by muse, mutect2
- IFT57 | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 108/697 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV52711205; called by muse, mutect2, varscan2
- IFT74 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 105/736 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV66287883, COSV66288200; called by muse, mutect2, varscan2
- IGF1R | c.2756C>A p.P919H | Missense Mutation (SNP) | VAF 32/957 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV99163264; called by muse, mutect2
- IGSF9 | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 62/500 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as rs1329518504; called by muse, mutect2, varscan2
- IL11 | c.540dup p.L181Afs*6 | Frame Shift Ins (INS) | VAF 29/206 reads (14%) | catalogued as rs768878885; called by mutect2, varscan2
- IL12RB1 | c.1970G>T p.R657M | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as rs866267146; called by muse, mutect2
- IL12RB1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 55/401 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as rs1568502518; called by muse, mutect2, varscan2
- IL12RB2 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 237/938 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52021372; called by muse, mutect2, varscan2
- IL1RAPL2 | c.230A>T p.Y77F | Missense Mutation (SNP) | VAF 208/662 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61176155; called by muse, varscan2
- IMPG1 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 161/541 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV64058249; called by muse, mutect2, varscan2
- INHBA | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 121/766 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs933197708, COSV54221206; called by muse, mutect2, varscan2
- INPP4B | c.730T>A p.S244T | Missense Mutation (SNP) | VAF 250/877 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.501); catalogued as COSV53727901; called by muse, mutect2, varscan2
- INSIG2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 144/893 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs137964264; called by muse, mutect2, varscan2
- INSR | c.3001A>G p.S1001G | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1364446814; called by muse, mutect2, varscan2
- IP6K1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 210/760 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs754942528; called by muse, mutect2, varscan2
- IPO7 | c.2947G>A p.G983S | Missense Mutation (SNP) | VAF 248/848 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1218385810; called by muse, mutect2, varscan2
- IPP | c.370C>A p.H124N | Missense Mutation (SNP) | VAF 116/771 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63432638; called by muse, mutect2, varscan2
- IQCA1 | c.1104dup p.Q369Tfs*10 | Frame Shift Ins (INS) | VAF 73/595 reads (12%) | catalogued as rs767039128; called by mutect2, varscan2
- IQCF1 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs199838926; called by muse, mutect2, varscan2
- IQCN | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as rs1372769527; called by muse, mutect2, varscan2
- IQUB | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 125/1525 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV61236746, COSV61241282; called by muse, mutect2
- IRF2BP2 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV64015709; called by muse, mutect2, varscan2
- IRGQ | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 66/179 reads (37%) | catalogued as COSV60670708; called by muse, mutect2, varscan2
- IRX2 | c.716A>G p.E239G | Missense Mutation (SNP) | VAF 104/288 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV57409873; called by muse, mutect2, varscan2
- ITFG1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 157/554 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.82); catalogued as rs11559042, COSV54534882; called by muse, mutect2, varscan2
- ITGA11 | c.1696dup p.L566Pfs*24 | Frame Shift Ins (INS) | VAF 84/276 reads (30%) | catalogued as rs1365968243; called by mutect2, varscan2
- ITGAE | c.2627G>T p.R876I | Missense Mutation (SNP) | VAF 125/443 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV54001127; called by muse, mutect2, varscan2
- ITGAL | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 48/433 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); catalogued as COSV63323569; called by muse, mutect2, varscan2
- ITPR1 | c.3712G>T p.A1238S (on ENST00000354582; = p.A1223S on NM_002222.7) | Missense Mutation (SNP) | VAF 63/483 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs749793481, COSV56968292; called by muse, mutect2, varscan2
- ITPR1 | c.7268G>T p.R2423I (on ENST00000354582; = p.R2368I on NM_002222.7) | Missense Mutation (SNP) | VAF 117/893 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV56990764; called by muse, mutect2, varscan2
- ITPR2 | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 102/858 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1283608902; called by muse, mutect2, varscan2
- ITPR3 | c.6839C>T p.P2280L | Missense Mutation (SNP) | VAF 71/512 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.11); catalogued as rs1210089283, COSV65411261; called by muse, mutect2, varscan2
- ITPR3 | c.7032+2T>C p.X2344_splice | Splice Site (SNP) | VAF 106/451 reads (24%) | catalogued as COSV65412824; called by muse, mutect2, varscan2
- ITPRIP | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs776526650; called by muse, mutect2, varscan2
- JADE2 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 146/501 reads (29%) | catalogued as rs61730676; called by muse, mutect2, varscan2
- JADE3 | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 404/1299 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1556372844; called by muse, mutect2, varscan2
- JARID2 | c.2993A>G p.H998R | Missense Mutation (SNP) | VAF 77/560 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.871); catalogued as COSV59192969; called by muse, mutect2, varscan2
- JDP2 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 154/559 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1465386223; called by muse, mutect2, varscan2
- JMJD1C | c.5644+2T>C p.X1882_splice | Splice Site (SNP) | VAF 100/761 reads (13%) | catalogued as COSV59517178; called by muse, mutect2, varscan2
- JOSD1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 234/871 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773785700; called by muse, mutect2, varscan2
- JRK | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs587744464; called by muse, mutect2, varscan2
- KAZN | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 126/410 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV63210343; called by muse, mutect2, varscan2
- KCNAB3 | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 233/761 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV58140388; called by muse, mutect2, varscan2
- KCNB2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 116/595 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); catalogued as COSV99074162; called by muse, mutect2, varscan2
- KCNG4 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 247/762 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779545766; called by muse, mutect2, varscan2
- KCNH8 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 52/1353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60461710; called by muse, mutect2
- KCNK15 | c.284-1G>T p.X95_splice | Splice Site (SNP) | VAF 39/151 reads (26%) | catalogued as COSV100865213; called by muse, mutect2, varscan2
- KCNK16 | c.330A>T p.G110= | Splice Region (SNP) | VAF 33/214 reads (15%) | catalogued as COSV100949116; called by muse, mutect2, varscan2
- KDM3A | c.309A>C p.E103D | Missense Mutation (SNP) | VAF 117/972 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.054); catalogued as rs201724307, COSV57220606; called by muse, mutect2, varscan2
- KDM3A | c.3020T>A p.V1007D | Missense Mutation (SNP) | VAF 120/1037 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57220721; called by muse, mutect2, varscan2
- KDM3B | c.5039C>T p.A1680V | Missense Mutation (SNP) | VAF 82/529 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.842); catalogued as COSV58695969; called by muse, mutect2, varscan2
- KDM4D | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782273063, COSV100624267; called by muse, mutect2, varscan2
- KDM4E | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71678318; called by muse, mutect2, varscan2
- KDM5A | c.4603A>G p.K1535E | Missense Mutation (SNP) | VAF 326/1185 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as rs770838673, COSV66996957; called by muse, mutect2, varscan2
- KDM5A | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 184/788 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66996911; called by muse, mutect2, varscan2
- KDM6A | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 108/859 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV65048386; called by muse, mutect2, varscan2
- KIAA1210 | c.1648T>G p.C550G | Missense Mutation (SNP) | VAF 146/531 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1279447942; called by muse, mutect2, varscan2
- KIAA1217 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 134/456 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335925039; called by muse, mutect2, varscan2
- KIAA1522 | c.2045C>T p.P682L (on ENST00000373480 / NM_001198972.2; = p.P741L on NM_020888.3) | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1420016665; called by muse, varscan2
- KIAA1549L | c.2305C>T p.P769S (on ENST00000321505; = p.P1066S on NM_012194.3) | Missense Mutation (SNP) | VAF 185/692 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs752165089; called by muse, mutect2, varscan2
- KIAA1586 | c.1750T>C p.S584P | Missense Mutation (SNP) | VAF 110/699 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1387772400; called by muse, mutect2, varscan2
- KIF13B | c.4282G>A p.A1428T | Missense Mutation (SNP) | VAF 132/358 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs749969830, COSV68094614; called by muse, mutect2, varscan2
- KIF20B | c.3866A>G p.K1289R (on ENST00000371728 / NM_001284259.2; = p.K1249R on NM_016195.4) | Missense Mutation (SNP) | VAF 142/1118 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as rs267602617; called by muse, varscan2
- KIF21B | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 143/472 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV59762816; called by muse, mutect2, varscan2
- KIF26A | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 70/281 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs780043191, COSV59467177; called by muse, mutect2, varscan2
- KIF4B | c.2302C>A p.L768I | Missense Mutation (SNP) | VAF 200/642 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV70531852; called by muse, varscan2
- KIF5B | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 153/1136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755716349; called by muse, mutect2, varscan2
- KIRREL3 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 231/774 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.95); catalogued as COSV101585872; called by muse, mutect2, varscan2
- KLC4 | c.1690A>G p.R564G | Missense Mutation (SNP) | VAF 149/607 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1333038324; called by muse, mutect2, varscan2
- KLHDC3 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 99/411 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV99763786; called by muse, mutect2, varscan2
- KLHDC4 | c.599+2T>C p.X200_splice | Splice Site (SNP) | VAF 78/596 reads (13%) | catalogued as rs769428361; called by muse, mutect2, varscan2
- KLHDC8A | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs768506470; called by muse, mutect2, varscan2
- KLHDC9 | c.387dup p.A130Rfs*5 | Frame Shift Ins (INS) | VAF 26/114 reads (23%) | catalogued as rs761803466; called by mutect2, varscan2
- KLHL3 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 78/672 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467261842, COSV59054804; called by muse, varscan2
- KLHL3 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 76/485 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59053216; called by muse, mutect2, varscan2
- KLHL33 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.83); catalogued as COSV60726768; called by muse, mutect2, varscan2
- KLK4 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759876755; called by muse, varscan2
- KPNB1 | c.1502C>A p.S501Y | Missense Mutation (SNP) | VAF 88/740 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV51599129, COSV51600832; called by muse, varscan2
- KRAS | c.469dup p.Y157Lfs*28 | Frame Shift Ins (INS) | VAF 242/942 reads (26%) | catalogued as rs869084357; called by mutect2, varscan2
- KRT12 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 97/639 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs767720536; called by muse, mutect2, varscan2
- KRT20 | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 283/944 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs779398705; called by muse, mutect2, varscan2
- KRTAP10-1 | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV59972532; called by muse, mutect2, varscan2
- KRTAP13-2 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 152/481 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV67761974; called by muse, mutect2, varscan2
- KRTAP13-3 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 30/712 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV61880540, COSV61880552; called by muse, mutect2
- KRTAP22-2 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 287/1100 reads (26%) | PolyPhen benign (0); catalogued as COSV99060496; called by muse, mutect2, varscan2
9,663 further variants in this file (5,791 protein-altering or splice-affecting, 1,776 silent, 2,096 other) are not listed here.
